Somatic mutation profile of tumor specimen ALCH-B2RC-TTP1-A (aliquot ALCH-B2RC-TTP1-A-2-0-D-A78Q-36) from ALCHEMIST case ALCH-B2RC, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 63.5 years (23,202 days).
Specimen ALCH-B2RC-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 336a76ea-8320-4398-956e-fb8db4d755e0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2RC-NB1-A (Blood Derived Normal), aliquot ALCH-B2RC-NB1-A-1-0-D-A78Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5855cc63-9b70-4edb-b949-6e720063b0b3

The open-access MAF lists 407 somatic variants for this specimen: 301 protein-altering or splice-affecting, 75 silent, 31 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 277, Silent 75, Nonsense Mutation 17, Intron 9, 5'UTR 8, RNA 6, 3'UTR 4, Splice Region 3, 3'Flank 2, 5'Flank 2, Splice Site 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGXT | c.198C>G p.Y66* | Nonsense Mutation (SNP) | VAF 47/420 reads (11%) | catalogued as rs121908521, CM910015, COSV56754894; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KLF5 | c.1255G>C p.E419Q | Missense Mutation (SNP) | VAF 47/357 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66613960, COSV66613967; called by muse, mutect2, varscan2
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 79/678 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.407A>C p.Q136P | Missense Mutation (SNP) | VAF 49/406 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1567554216, COSV52751724, COSV52782611, COSV52910696, COSV53122800; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABLIM1 | c.1516G>C p.A506P | Missense Mutation (SNP) | VAF 21/331 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as rs777212178; called by muse, mutect2
- ADAMTS19 | c.1328G>T p.R443M | Missense Mutation (SNP) | VAF 22/315 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV50735197, COSV99178846; called by muse, mutect2
- ADGRL3 | c.11C>A p.S4* | Nonsense Mutation (SNP) | VAF 32/504 reads (6%) | catalogued as COSV72268560; called by muse, mutect2
- ALDH8A1 | c.326G>C p.R109P | Missense Mutation (SNP) | VAF 29/254 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99665019; called by muse, mutect2, varscan2
- ALK | c.4169C>A p.P1390Q | Missense Mutation (SNP) | VAF 34/521 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66590070; called by muse, mutect2
- BRINP2 | c.1940G>A p.R647Q | Missense Mutation (SNP) | VAF 70/787 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1266621387, COSV64176570; called by muse, mutect2
- C2 | c.829G>A p.A277T | Missense Mutation (SNP) | VAF 18/529 reads (3%) | SIFT tolerated (0.16); PolyPhen benign (0.11); catalogued as rs771207793, COSV54960325; called by muse, mutect2
- C6orf118 | c.1406G>T p.R469I | Missense Mutation (SNP) | VAF 22/347 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.178); catalogued as COSV57812452, COSV57820196; called by muse, mutect2
- CAPN9 | c.31C>T p.Q11* | Nonsense Mutation (SNP) | VAF 69/500 reads (14%) | catalogued as COSV55239480; called by muse, mutect2, varscan2
- CDKL5 | c.1892T>C p.I631T | Missense Mutation (SNP) | VAF 36/444 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs144878564; ClinVar: uncertain significance / likely benign; called by muse, mutect2
- CFAP74 | c.1432G>T p.V478L | Missense Mutation (SNP) | VAF 23/191 reads (12%) | SIFT tolerated (0.76); PolyPhen benign (0.063); catalogued as COSV54571500; called by muse, mutect2, varscan2
- COL22A1 | c.664C>G p.L222V | Missense Mutation (SNP) | VAF 28/600 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.237); catalogued as COSV100277062; called by muse, mutect2
- COL3A1 | c.1160G>T p.G387V | Missense Mutation (SNP) | VAF 110/1088 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58586183; called by muse, mutect2
- CPNE3 | c.662G>T p.G221V | Missense Mutation (SNP) | VAF 42/355 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52207363; called by muse, mutect2, varscan2
- CSHL1 | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 101/1048 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs199647188, COSV51990332; called by muse, mutect2
- CTBP1 | c.356A>T p.N119I | Missense Mutation (SNP) | VAF 32/226 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99337791; called by muse, mutect2, varscan2
- CUX1 | c.2005G>A p.E669K | Missense Mutation (SNP) | VAF 42/414 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); catalogued as rs1554519236; called by muse, mutect2
- DIP2A | c.4585G>T p.V1529L | Missense Mutation (SNP) | VAF 46/463 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV100595032; called by muse, mutect2, varscan2
- DNAH11 | c.1967G>T p.R656L | Missense Mutation (SNP) | VAF 65/711 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.068); catalogued as COSV60940833; called by muse, mutect2
- DNAH11 | c.3593C>T p.T1198I | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV60947403; called by muse, mutect2
- DST | c.9136G>A p.G3046R | Missense Mutation (SNP) | VAF 38/544 reads (7%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.015); catalogued as rs760629490; called by muse, mutect2
- DTHD1 | c.2227C>A p.L743I (on ENST00000456874; = p.L578I on NM_001136536.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 77/680 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.736); catalogued as COSV62631031; called by muse, mutect2, varscan2
- EDN1 | c.314G>A p.R105H | Missense Mutation (SNP) | VAF 28/436 reads (6%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs140854546; called by muse, mutect2
- EPX | c.860C>G p.S287W | Missense Mutation (SNP) | VAF 35/366 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99836868; called by muse, mutect2
- EZHIP | c.599C>A p.P200H | Missense Mutation (SNP) | VAF 15/150 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100539809; called by muse, mutect2
- F10 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 63/647 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.932); catalogued as rs1385231235; called by muse, mutect2
- FAM189A1 | c.859G>T p.G287C | Missense Mutation (SNP) | VAF 26/299 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs762465774; called by muse, mutect2
- FAM83B | c.1955A>G p.K652R | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV100175086, COSV60920419; called by muse, mutect2
- FAT1 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 53/552 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101499519; called by muse, mutect2
- FGFR2 | c.1751T>C p.M584T | Missense Mutation (SNP) | VAF 32/659 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.081); catalogued as COSV60638913; called by muse, mutect2
- FHAD1 | c.1657G>T p.E553* | Nonsense Mutation (SNP) | VAF 42/426 reads (10%) | catalogued as rs1392030748; called by muse, mutect2, varscan2
- FLG | c.9362G>T p.R3121M | Missense Mutation (SNP) | VAF 72/952 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV64243171; called by muse, mutect2
- GLI3 | c.2962G>C p.G988R | Missense Mutation (SNP) | VAF 40/322 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.013); catalogued as rs765236732, COSV101229894; called by muse, mutect2, varscan2
- GPLD1 | c.1545G>C p.W515C | Missense Mutation (SNP) | VAF 18/220 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs905869698, COSV100015639; called by muse, mutect2
- GPR26 | c.980C>G p.S327C | Missense Mutation (SNP) | VAF 42/461 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.747); catalogued as COSV99500801; called by muse, mutect2
- GPR89B | c.162G>T p.M54I | Missense Mutation (SNP) | VAF 55/864 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as rs1553248415; called by muse, mutect2
- GRIN3A | c.1529C>T p.P510L | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.028); catalogued as rs201751805; called by muse, mutect2, varscan2
- HIF3A | c.1139G>T p.S380I (on ENST00000377670 / NM_152795.4; = p.S311I on NM_022462.4) | Missense Mutation (SNP) | VAF 22/222 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.085); catalogued as COSV99355464; called by muse, mutect2
- HTR3E | c.1132C>T p.H378Y (on ENST00000415389 / NM_001256613.1; = p.H393Y on NM_182589.2) | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs1219609106; called by muse, mutect2
- IGHV4-61 | c.45A>T p.R15S | Missense Mutation (SNP) | VAF 76/434 reads (18%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.021); catalogued as rs782310445; called by muse, mutect2, varscan2
- IGLV2-23 | c.224G>T p.R75L | Missense Mutation (SNP) | VAF 107/994 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.85); catalogued as rs374955184; called by muse, mutect2, varscan2
- IL21 | c.322C>T p.P108S | Missense Mutation (SNP) | VAF 14/355 reads (4%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.995); catalogued as rs1377593692; called by muse, mutect2
- ITGB8 | c.505G>A p.V169I | Missense Mutation (SNP) | VAF 41/498 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.063); catalogued as rs768194871, COSV56004933; called by muse, mutect2
- KCNJ3 | c.823G>A p.D275N | Missense Mutation (SNP) | VAF 68/772 reads (9%) | SIFT tolerated (0.95); PolyPhen benign (0.012); catalogued as rs201650481, COSV54544929, COSV99716544; called by muse, mutect2
- KIF2B | c.322G>T p.D108Y | Missense Mutation (SNP) | VAF 21/252 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.733); catalogued as COSV52131041; called by muse, mutect2
- KIF3C | c.2215A>G p.M739V | Missense Mutation (SNP) | VAF 28/347 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs771892151; called by muse, mutect2
- KRTAP10-2 | c.479C>T p.S160F | Missense Mutation (SNP) | VAF 93/792 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.697); catalogued as rs1555918653, COSV100554902; called by muse, varscan2
- LIN28B | c.574C>T p.P192S | Missense Mutation (SNP) | VAF 50/518 reads (10%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.026); catalogued as COSV100559135; called by muse, mutect2
- LMNB2 | c.1244C>A p.S415* | Nonsense Mutation (SNP) | VAF 23/179 reads (13%) | catalogued as COSV100322244; called by muse, mutect2, varscan2
- LRRN3 | c.19C>G p.R7G | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV57817640; called by muse, mutect2, varscan2
- MAPK8IP3 | c.2065G>T p.V689L | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT tolerated (0.82); PolyPhen probably damaging (0.992); catalogued as rs1194869207, COSV99167720; called by muse, mutect2, varscan2
- MARCO | c.1347C>A p.D449E | Missense Mutation (SNP) | VAF 28/574 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59056391; called by muse, mutect2
- MNDA | c.722C>A p.A241D | Missense Mutation (SNP) | VAF 50/566 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV63740677; called by muse, mutect2
- MYH11 | c.2762A>T p.E921V | Missense Mutation (SNP) | VAF 50/966 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55561031; called by muse, mutect2
- MYOC | c.137G>T p.R46L | Missense Mutation (SNP) | VAF 131/823 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as COSV104377617; called by muse, mutect2, varscan2
- MYOM2 | c.3284G>T p.G1095V | Missense Mutation (SNP) | VAF 17/344 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50741858; called by muse, mutect2
- MYOZ2 | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 48/784 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.033); catalogued as rs753997345; ClinVar: uncertain significance; called by muse, mutect2
- NCAPD3 | c.3416G>T p.S1139I | Missense Mutation (SNP) | VAF 107/975 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV101594444; called by muse, mutect2, varscan2
- NCF1 | c.556G>A p.V186I | Missense Mutation (SNP) | VAF 32/988 reads (3%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.551); catalogued as rs1342608126, COSV99194322; called by muse, mutect2
- NLRC5 | c.4751G>A p.R1584K | Missense Mutation (SNP) | VAF 22/454 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0.078); catalogued as COSV99347268; called by muse, mutect2
- NPSR1 | c.953T>A p.L318Q | Missense Mutation (SNP) | VAF 50/627 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100706076; called by muse, mutect2
- OR11L1 | c.899C>A p.A300D | Missense Mutation (SNP) | VAF 26/296 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV63315093; called by muse, mutect2
- OR14A2 | c.832G>A p.V278M | Missense Mutation (SNP) | VAF 36/590 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.622); catalogued as COSV99057563; called by muse, mutect2
- OR2G3 | c.919G>T p.G307* | Nonsense Mutation (SNP) | VAF 12/80 reads (15%) | catalogued as COSV60680873; called by muse, varscan2
- OR2L13 | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 26/388 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV63557684; called by muse, mutect2
- OSMR | c.181C>T p.Q61* | Nonsense Mutation (SNP) | VAF 32/418 reads (8%) | catalogued as COSV99953528; called by muse, mutect2
- PAK5 | c.352G>T p.G118C | Missense Mutation (SNP) | VAF 60/738 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.707); catalogued as COSV62024256; called by muse, mutect2
- PCDH10 | c.1382C>A p.P461Q | Missense Mutation (SNP) | VAF 34/465 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV52106296; called by muse, mutect2
- PCDHGB2 | c.304T>C p.C102R | Missense Mutation (SNP) | VAF 24/540 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV53997756; called by muse, mutect2
- PDP1 | c.38G>T p.R13L | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.264); catalogued as COSV52600200, COSV52602449; called by muse, mutect2
- PGR | c.2696G>T p.R899L | Missense Mutation (SNP) | VAF 58/824 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV54797337, COSV54798889; called by muse, mutect2
- PHYKPL | c.81dup p.P28Sfs*6 | Frame Shift Ins (INS) | VAF 58/545 reads (11%) | catalogued as rs530484554; called by mutect2, pindel
- PLCE1 | c.1936G>C p.E646Q | Missense Mutation (SNP) | VAF 35/950 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1158028629, COSV53367836; called by muse, mutect2
- PLCL1 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 37/544 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV70820741; called by muse, mutect2
- PLOD3 | c.538G>T p.V180L | Missense Mutation (SNP) | VAF 149/734 reads (20%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.998); catalogued as COSV99778022; called by muse, mutect2, varscan2
- PTPN14 | c.2426C>A p.S809* | Nonsense Mutation (SNP) | VAF 65/542 reads (12%) | catalogued as COSV104423758; called by muse, mutect2, varscan2
- PTPRD | c.1034C>A p.S345Y | Missense Mutation (SNP) | VAF 22/288 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.53); catalogued as COSV61987068; called by muse, mutect2
- RAPGEF3 | c.1884G>T p.E628D (on ENST00000389212; = p.E586D on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/418 reads (12%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.704); catalogued as COSV50243795; called by muse, mutect2, varscan2
- RBMXL2 | c.774C>G p.S258R | Missense Mutation (SNP) | VAF 24/224 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.162); catalogued as rs201798501, COSV60979246, COSV99080268; called by muse, mutect2, varscan2
- RBP3 | c.2152C>A p.P718T | Missense Mutation (SNP) | VAF 25/338 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.323); catalogued as rs781813519; called by muse, mutect2
- RYR2 | c.1022G>C p.G341A | Missense Mutation (SNP) | VAF 40/346 reads (12%) | SIFT tolerated (0.94); PolyPhen possibly damaging (0.856); catalogued as rs565413020, COSV63706277; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- RYR2 | c.2359C>A p.L787I | Missense Mutation (SNP) | VAF 30/628 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV63719195; called by muse, mutect2
- SFRP1 | c.131G>A p.G44D | Missense Mutation (SNP) | VAF 42/532 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.418); catalogued as rs866487203; called by muse, mutect2
- SHBG | c.316G>C p.E106Q | Missense Mutation (SNP) | VAF 31/339 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52646765; called by muse, mutect2
- SLC26A7 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 16/265 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs866023753, COSV52590967; called by muse, mutect2
- SLC35F1 | c.640G>T p.E214* | Nonsense Mutation (SNP) | VAF 28/154 reads (18%) | catalogued as COSV64504632; called by muse, mutect2
- SLC6A19 | c.1669G>C p.E557Q | Missense Mutation (SNP) | VAF 27/518 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.009); catalogued as COSV57255637; called by muse, mutect2
- SMC2 | c.724G>T p.A242S | Missense Mutation (SNP) | VAF 132/611 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.449); catalogued as rs993032742; called by muse, mutect2, varscan2
- SORBS2 | c.83G>C p.G28A (on ENST00000284776 / NM_021069.5; = p.G74A on NM_003603.6) | Missense Mutation (SNP) | VAF 17/271 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.338); catalogued as rs139155954; called by muse, mutect2
- SPATA6L | c.991G>A p.E331K (on ENST00000461761 / NM_001353484.2; = p.E273K on NM_001039395.4 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV67889873; called by muse, mutect2
- SPTBN1 | c.6310G>A p.E2104K | Missense Mutation (SNP) | VAF 56/712 reads (8%) | SIFT tolerated (0.77); PolyPhen benign (0.011); catalogued as rs936886115; called by muse, mutect2
- SRPX2 | c.911G>A p.R304Q | Missense Mutation (SNP) | VAF 102/448 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs778904903, COSV65934750; called by muse, mutect2, varscan2
- STAB2 | c.1899G>A p.M633I | Missense Mutation (SNP) | VAF 33/250 reads (13%) | SIFT tolerated (0.68); PolyPhen benign (0.005); catalogued as rs771707659; called by muse, mutect2, varscan2
- TENM2 | c.542C>A p.P181Q | Missense Mutation (SNP) | VAF 40/649 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.44); catalogued as COSV69139459; called by muse, mutect2
- TGIF2LX | c.345G>T p.Q115H | Missense Mutation (SNP) | VAF 111/715 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.259); catalogued as COSV52215071, COSV52215552; called by muse, mutect2, varscan2
- THSD7B | c.626C>T p.P209L | Missense Mutation (SNP) | VAF 36/608 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.104); catalogued as rs1457774852, COSV99745022; called by muse, mutect2
- TMC3 | c.982C>T p.L328F | Missense Mutation (SNP) | VAF 29/362 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.577); catalogued as rs377245834; called by muse, mutect2
- TNNI3 | c.422G>T p.R141L | Missense Mutation (SNP) | VAF 54/511 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as CM031378, COSV52573447; called by muse, mutect2, varscan2
- USH2A | c.5916G>T p.E1972D | Missense Mutation (SNP) | VAF 173/983 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.339); catalogued as COSV56332289; called by muse, mutect2, varscan2
- WFIKKN1 | c.605C>A p.T202K | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs865864230; called by muse, mutect2, varscan2
- XIRP2 | c.3126G>T p.E1042D (on ENST00000628543; = p.E1217D on NM_152381.6) | Missense Mutation (SNP) | VAF 14/264 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.411); catalogued as COSV54700086; called by muse, mutect2
- XIRP2 | c.6308C>A p.P2103H (on ENST00000628543; = p.P2278H on NM_152381.6) | Missense Mutation (SNP) | VAF 30/554 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV54732780; called by muse, mutect2
- ZNF467 | c.1352G>T p.R451L | Missense Mutation (SNP) | VAF 22/231 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100118064; called by muse, mutect2
- ACSM1 | c.1197G>A p.Q399= | Splice Region (SNP) | VAF 20/431 reads (5%) | called by muse, mutect2
- ACSS1 | c.496G>T p.D166Y | Missense Mutation (SNP) | VAF 82/920 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADAMTS19 | c.2388G>T p.K796N | Missense Mutation (SNP) | VAF 18/295 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); called by muse, mutect2
- ADGRA3 | c.59C>T p.S20L | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.32); called by muse, mutect2
- ADGRE5 | c.2005G>T p.V669F (on ENST00000242786 / NM_078481.4; = p.V576F on NM_001784.5) | Missense Mutation (SNP) | VAF 72/429 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- ALMS1 | c.2197A>T p.S733C | Missense Mutation (SNP) | VAF 69/976 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2
- AQP4 | c.401A>T p.Y134F | Missense Mutation (SNP) | VAF 66/698 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.22); called by muse, mutect2
- ARAP3 | c.3076G>T p.V1026F | Missense Mutation (SNP) | VAF 55/428 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- ATP1A4 | c.70G>T p.G24W | Missense Mutation (SNP) | VAF 26/418 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.406); called by muse, mutect2
- ATP8A1 | c.761G>T p.G254V | Missense Mutation (SNP) | VAF 52/592 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- C6orf89 | c.929C>T p.P310L (on ENST00000373685; = p.P317L on NM_152734.4) | Missense Mutation (SNP) | VAF 29/280 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- CACNG8 | c.607G>C p.G203R | Missense Mutation (SNP) | VAF 76/776 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CCDC168 | c.8634G>T p.R2878S | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT tolerated (0.74); PolyPhen benign (0.015); called by muse, mutect2
- CCZ1B | c.156G>T p.E52D | Missense Mutation (SNP) | VAF 22/261 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CD109 | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 41/526 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.092); called by muse, mutect2
- CDH10 | c.565G>T p.D189Y | Missense Mutation (SNP) | VAF 14/312 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CHRM5 | c.1272T>A p.H424Q | Missense Mutation (SNP) | VAF 18/438 reads (4%) | SIFT tolerated (0.42); PolyPhen benign (0.215); called by muse, mutect2
- CLASP1 | c.1261A>T p.S421C | Missense Mutation (SNP) | VAF 30/314 reads (10%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.863); called by muse, mutect2
- CNTNAP5 | c.268G>T p.A90S | Missense Mutation (SNP) | VAF 38/610 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.334); called by muse, mutect2
- COL22A1 | c.1799A>G p.E600G | Missense Mutation (SNP) | VAF 20/640 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.723); called by muse, mutect2
- COL3A1 | c.1213G>T p.G405* | Nonsense Mutation (SNP) | VAF 104/1478 reads (7%) | called by muse, mutect2
- COL4A1 | c.3335G>T p.G1112V | Missense Mutation (SNP) | VAF 74/1073 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- COLEC11 | c.314C>A p.P105H | Missense Mutation (SNP) | VAF 93/940 reads (10%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.975); called by muse, mutect2
- COX10 | c.428G>A p.W143* | Nonsense Mutation (SNP) | VAF 44/384 reads (11%) | called by muse, mutect2, varscan2
- CPEB4 | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.184); called by muse, mutect2
- CTR9 | c.1054A>G p.I352V | Missense Mutation (SNP) | VAF 46/290 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- CYP11B2 | c.914A>T p.K305M | Missense Mutation (SNP) | VAF 46/694 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.692); called by muse, mutect2
- CYP4F8 | c.107C>A p.A36D | Missense Mutation (SNP) | VAF 37/413 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.013); called by muse, mutect2
- DAGLA | c.2884G>T p.A962S | Missense Mutation (SNP) | VAF 34/347 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.287); called by muse, mutect2
- DLGAP4 | c.1726G>T p.V576F | Missense Mutation (SNP) | VAF 36/272 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DMXL1 | c.5992G>A p.D1998N | Missense Mutation (SNP) | VAF 14/273 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2
- DNAAF5 | c.1714G>C p.A572P | Missense Mutation (SNP) | VAF 68/620 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- DNAH11 | c.2532G>T p.W844C | Missense Mutation (SNP) | VAF 46/514 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2
- DNHD1 | c.5612C>A p.P1871H | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- DPP9 | c.543G>T p.K181N (on ENST00000598800; = p.K210N on NM_139159.5) | Missense Mutation (SNP) | VAF 36/267 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- DRAXIN | c.773A>C p.K258T | Missense Mutation (SNP) | VAF 24/314 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.124); called by muse, mutect2
- DSEL | c.1207G>T p.D403Y | Missense Mutation (SNP) | VAF 34/392 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EDEM3 | c.1762C>T p.H588Y | Missense Mutation (SNP) | VAF 21/646 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ELMO1 | c.939G>T p.M313I | Missense Mutation (SNP) | VAF 30/328 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.124); called by muse, mutect2
- EPAS1 | c.382G>A p.G128R | Missense Mutation (SNP) | VAF 42/1059 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EPHA7 | c.2843G>T p.G948V | Missense Mutation (SNP) | VAF 48/657 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ERN2 | c.2617C>A p.Q873K | Missense Mutation (SNP) | VAF 55/517 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- FAM86DP | n.513G>C | Splice Region (SNP) | VAF 56/546 reads (10%) | called by muse, mutect2, varscan2
- FBXO40 | c.1793A>T p.Q598L | Missense Mutation (SNP) | VAF 157/874 reads (18%) | SIFT tolerated (1); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- FCGR1A | c.286A>T p.I96L | Missense Mutation (SNP) | VAF 186/1577 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2
- FCRL4 | c.1491G>T p.K497N | Missense Mutation (SNP) | VAF 75/845 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.132); called by muse, mutect2
- FCRL5 | c.7C>G p.L3V | Missense Mutation (SNP) | VAF 113/873 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- FETUB | c.997A>T p.N333Y | Missense Mutation (SNP) | VAF 54/320 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- FLG2 | c.4160G>C p.R1387T | Missense Mutation (SNP) | VAF 62/481 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- GAD2 | c.1677G>T p.M559I | Missense Mutation (SNP) | VAF 41/690 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.068); called by muse, mutect2
- GC | c.226G>T p.A76S | Missense Mutation (SNP) | VAF 26/330 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.115); called by muse, mutect2
- GCNT7 | c.853C>A p.Q285K | Missense Mutation (SNP) | VAF 54/768 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.202); called by muse, mutect2
- GDF10 | c.883A>G p.T295A | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2
- GFRA1 | c.1298C>A p.T433K | Missense Mutation (SNP) | VAF 81/790 reads (10%) | SIFT tolerated (0.58); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- GLYAT | c.844G>C p.V282L | Missense Mutation (SNP) | VAF 12/153 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.014); called by muse, mutect2
- HARS1 | c.979G>T p.G327W | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HBEGF | c.166G>T p.G56C | Missense Mutation (SNP) | VAF 80/867 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.371); called by muse, mutect2
- HECW1 | c.755G>A p.R252K | Missense Mutation (SNP) | VAF 22/250 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); called by muse, mutect2
- HELZ2 | c.4267G>C p.D1423H (on ENST00000467148 / NM_001037335.2; = p.D854H on NM_033405.3) | Missense Mutation (SNP) | VAF 23/362 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); called by muse, mutect2
- HIF3A | c.1138A>C p.S380R (on ENST00000377670 / NM_152795.4; = p.S311R on NM_022462.4) | Missense Mutation (SNP) | VAF 21/228 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2
- HLA-DMA | c.718G>A p.G240S | Missense Mutation (SNP) | VAF 33/616 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- HMX3 | c.668C>A p.P223Q | Missense Mutation (SNP) | VAF 22/424 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.451); called by muse, mutect2
- IGKV1-17 | c.304C>G p.P102A | Missense Mutation (SNP) | VAF 68/737 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- IGKV3-20 | c.125C>A p.S42Y | Missense Mutation (SNP) | VAF 108/1275 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2
- IKZF2 | c.635A>T p.E212V | Missense Mutation (SNP) | VAF 35/554 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- IL17RD | c.886G>T p.G296W | Missense Mutation (SNP) | VAF 15/220 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- IL5RA | c.1240A>T p.T414S | Missense Mutation (SNP) | VAF 71/404 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- INPP4B | c.1430G>T p.R477M | Missense Mutation (SNP) | VAF 22/257 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2
- INSIG1 | c.111G>T p.M37I | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- ITIH1 | c.653C>G p.A218G | Missense Mutation (SNP) | VAF 40/506 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.001); called by muse, mutect2
- KCNB2 | c.2074C>A p.Q692K | Missense Mutation (SNP) | VAF 29/704 reads (4%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0.021); called by muse, mutect2
- KCNH6 | c.1324G>A p.V442M | Missense Mutation (SNP) | VAF 26/355 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.065); called by muse, mutect2
- KCNH7 | c.3544G>C p.V1182L | Missense Mutation (SNP) | VAF 24/213 reads (11%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNIP4 | c.271T>A p.Y91N | Missense Mutation (SNP) | VAF 40/314 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2
- KIAA1217 | c.2548A>C p.K850Q | Missense Mutation (SNP) | VAF 59/509 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- KIF1A | c.1868A>T p.Q623L | Missense Mutation (SNP) | VAF 39/445 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KRTAP9-3 | c.65C>A p.T22N | Missense Mutation (SNP) | VAF 22/457 reads (5%) | SIFT deleterious (0.01); called by muse, mutect2
- LCLAT1 | c.130G>T p.G44W | Missense Mutation (SNP) | VAF 23/254 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LEO1 | c.230G>T p.S77I | Missense Mutation (SNP) | VAF 18/181 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- LGR5 | c.631A>C p.S211R | Missense Mutation (SNP) | VAF 30/338 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.737); called by muse, mutect2
- LPL | c.957A>T p.K319N | Missense Mutation (SNP) | VAF 26/700 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); called by muse, mutect2
- LRBA | c.6277G>T p.V2093L | Missense Mutation (SNP) | VAF 24/339 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2
- LRCH4 | c.43G>C p.E15Q | Missense Mutation (SNP) | VAF 76/317 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- LRP1B | c.2731T>C p.C911R | Missense Mutation (SNP) | VAF 36/548 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LRP1B | c.2597G>T p.G866V | Missense Mutation (SNP) | VAF 26/426 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LVRN | c.2392G>T p.D798Y | Missense Mutation (SNP) | VAF 26/475 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MAGEB6B | c.352G>T p.G118C | Missense Mutation (SNP) | VAF 27/237 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- MAP10 | c.2066G>T p.S689I | Missense Mutation (SNP) | VAF 26/202 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); called by muse, varscan2
- METTL9 | c.116G>T p.G39V | Missense Mutation (SNP) | VAF 27/421 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2
- MMP19 | c.1417C>A p.R473S | Missense Mutation (SNP) | VAF 19/196 reads (10%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MRO | c.64C>A p.Q22K | Missense Mutation (SNP) | VAF 30/338 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- MUC17 | c.5101C>A p.P1701T | Missense Mutation (SNP) | VAF 44/216 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYH11 | c.2761G>T p.E921* | Nonsense Mutation (SNP) | VAF 54/962 reads (6%) | called by muse, mutect2
- MYH7B | c.5704G>T p.A1902S | Missense Mutation (SNP) | VAF 76/558 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- NLRP3 | c.1400T>A p.L467H | Missense Mutation (SNP) | VAF 37/268 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NOS2 | c.2012G>T p.S671I | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- NOS3 | c.567G>T p.Q189H | Missense Mutation (SNP) | VAF 35/195 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NXF3 | c.839C>A p.A280E | Missense Mutation (SNP) | VAF 30/159 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- OR4D6 | c.136G>A p.V46M | Missense Mutation (SNP) | VAF 41/509 reads (8%) | SIFT tolerated (0.84); PolyPhen benign (0.024); called by muse, mutect2
- OR8H1 | c.781C>A p.P261T | Missense Mutation (SNP) | VAF 27/241 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- OR8K1 | c.527G>T p.G176V | Missense Mutation (SNP) | VAF 30/423 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.905); called by muse, mutect2
- OTOL1 | c.455-1G>T p.X152_splice | Splice Site (SNP) | VAF 75/384 reads (20%) | called by muse, mutect2, varscan2
- P4HB | c.1081C>A p.P361T | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2
- PAGE2B | c.184G>C p.A62P | Missense Mutation (SNP) | VAF 31/210 reads (15%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCDH10 | c.3059G>T p.G1020V | Missense Mutation (SNP) | VAF 26/271 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.376); called by muse, mutect2
- PCDH17 | c.3334A>G p.S1112G | Missense Mutation (SNP) | VAF 60/798 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2
- PCDH7 | c.2638G>T p.G880C | Missense Mutation (SNP) | VAF 80/533 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHA12 | c.1205A>G p.K402R | Missense Mutation (SNP) | VAF 40/983 reads (4%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.301); called by muse, mutect2
- PCDHB3 | c.580C>G p.L194V | Missense Mutation (SNP) | VAF 29/672 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCDHGA4 | c.1432G>T p.D478Y | Missense Mutation (SNP) | VAF 37/437 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- PHLPP2 | c.2906C>T p.S969F | Missense Mutation (SNP) | VAF 51/510 reads (10%) | SIFT tolerated (0.67); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- PKD1 | c.1484G>T p.W495L | Missense Mutation (SNP) | VAF 22/684 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); called by muse, mutect2
- PLCB1 | c.1453C>A p.Q485K | Missense Mutation (SNP) | VAF 16/414 reads (4%) | SIFT tolerated (0.32); PolyPhen benign (0.085); called by muse, mutect2
- PLCL1 | c.649G>T p.G217W | Missense Mutation (SNP) | VAF 23/295 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PLCL1 | c.1979G>T p.W660L | Missense Mutation (SNP) | VAF 21/234 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PLEKHG6 | c.1199T>A p.L400Q | Missense Mutation (SNP) | VAF 38/266 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- POM121L2 | c.634C>G p.P212A | Missense Mutation (SNP) | VAF 26/492 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.642); called by muse, mutect2
- PPP4R3C | c.1750C>T p.P584S | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRAMEF20 | c.925G>C p.D309H | Missense Mutation (SNP) | VAF 32/912 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- PRMT6 | c.155C>T p.S52L | Missense Mutation (SNP) | VAF 17/221 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.285); called by muse, mutect2
- PTCHD4 | c.1552G>T p.V518L | Missense Mutation (SNP) | VAF 20/386 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.864); called by muse, mutect2
- PTPRQ | c.6494C>A p.T2165K (on ENST00000616559; = p.T2132K on NM_001145026.2) | Missense Mutation (SNP) | VAF 32/372 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.395); called by muse, mutect2
- PUM2 | c.254C>A p.S85* | Nonsense Mutation (SNP) | VAF 67/586 reads (11%) | called by muse, mutect2, varscan2
- PXDNL | c.3969C>A p.Y1323* | Nonsense Mutation (SNP) | VAF 16/390 reads (4%) | called by muse, mutect2
- QRICH1 | c.838G>T p.V280L | Missense Mutation (SNP) | VAF 38/450 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.047); called by muse, mutect2
- RECQL | c.790G>T p.D264Y | Missense Mutation (SNP) | VAF 34/492 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- REG3G | c.370A>T p.S124C | Missense Mutation (SNP) | VAF 47/528 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); called by muse, mutect2
- RGS18 | c.584C>A p.S195Y | Missense Mutation (SNP) | VAF 68/609 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RMDN1 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 14/232 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.328); called by muse, mutect2
- RNF145 | c.322G>C p.A108P (on ENST00000424310 / NM_001199383.2; = p.A136P on NM_144726.2) | Missense Mutation (SNP) | VAF 24/474 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.209); called by muse, mutect2
- RNF8 | c.869A>G p.Q290R | Missense Mutation (SNP) | VAF 61/699 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2
- ROR1 | c.13C>T p.R5C | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- RSF1 | c.2962G>A p.D988N | Missense Mutation (SNP) | VAF 22/179 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- RUFY2 | c.1305A>T p.E435D | Missense Mutation (SNP) | VAF 36/324 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- RYR3 | c.9823A>T p.N3275Y (on ENST00000389232; = p.N3276Y on NM_001036.6) | Missense Mutation (SNP) | VAF 10/181 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- SATB2 | c.690G>T p.K230N | Missense Mutation (SNP) | VAF 38/566 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2
- SCN3A | c.2825G>T p.G942V | Missense Mutation (SNP) | VAF 92/1466 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SDK1 | c.4800+1G>T p.X1600_splice | Splice Site (SNP) | VAF 35/324 reads (11%) | called by muse, mutect2, varscan2
- SERPINB2 | c.452C>T p.S151L | Missense Mutation (SNP) | VAF 60/731 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.01); called by muse, mutect2
- SH3RF3 | c.1586G>T p.G529V | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); called by muse, mutect2
- SH3TC2 | c.3214C>A p.Q1072K | Missense Mutation (SNP) | VAF 36/448 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.041); called by muse, mutect2
- SHPRH | c.1117G>C p.D373H | Missense Mutation (SNP) | VAF 55/573 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC25A17 | c.241G>A p.V81I | Missense Mutation (SNP) | VAF 32/450 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.277); called by muse, mutect2
- SLIT1 | c.4472C>A p.S1491* | Nonsense Mutation (SNP) | VAF 36/598 reads (6%) | called by muse, mutect2
- SLIT3 | c.1205T>C p.L402P | Missense Mutation (SNP) | VAF 20/412 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLITRK1 | c.371A>C p.Q124P | Missense Mutation (SNP) | VAF 64/976 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.334); called by muse, mutect2
- SLITRK4 | c.1164C>A p.S388R | Missense Mutation (SNP) | VAF 57/267 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SNTG1 | c.153C>G p.F51L | Missense Mutation (SNP) | VAF 15/302 reads (5%) | SIFT tolerated (0.65); PolyPhen benign (0.107); called by muse, mutect2
- SPART | c.245A>G p.K82R | Missense Mutation (SNP) | VAF 16/208 reads (8%) | SIFT tolerated (0.86); PolyPhen benign (0.009); called by muse, mutect2
- SPATS1 | c.207T>A p.S69R | Missense Mutation (SNP) | VAF 48/548 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SPNS2 | c.103G>T p.G35C | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.486); called by muse, mutect2
- SPOCK3 | c.209T>A p.F70Y | Missense Mutation (SNP) | VAF 22/371 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.572); called by muse, mutect2
- SPTA1 | c.6806G>A p.S2269N | Missense Mutation (SNP) | VAF 54/485 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- SRPX | c.1327G>C p.D443H | Missense Mutation (SNP) | VAF 19/231 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ST18 | c.680A>G p.K227R | Missense Mutation (SNP) | VAF 11/377 reads (3%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, mutect2
- ST7L | c.725T>G p.L242R | Missense Mutation (SNP) | VAF 27/252 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- STAG3 | c.1964C>T p.P655L | Missense Mutation (SNP) | VAF 123/652 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- STK31 | c.2194G>A p.D732N | Missense Mutation (SNP) | VAF 41/406 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- STK32C | c.1186C>T p.H396Y | Missense Mutation (SNP) | VAF 14/322 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- SYNE1 | c.10481A>C p.H3494P (on ENST00000367255 / NM_182961.4; = p.H3501P on NM_033071.3) | Missense Mutation (SNP) | VAF 87/839 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TACC1 | c.399G>T p.K133N | Missense Mutation (SNP) | VAF 41/594 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.143); called by muse, mutect2
- TACR3 | c.935G>T p.W312L | Missense Mutation (SNP) | VAF 40/469 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- TARS3 | c.1604G>T p.R535M | Missense Mutation (SNP) | VAF 18/262 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TCF24 | c.181C>G p.R61G | Missense Mutation (SNP) | VAF 22/279 reads (8%) | SIFT deleterious (0); called by muse, mutect2
- TCP11X2 | c.810G>T p.M270I | Missense Mutation (SNP) | VAF 122/1452 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2
- TCP11X2 | c.809T>A p.M270K | Missense Mutation (SNP) | VAF 120/1441 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, mutect2
- TDRD15 | c.2825C>A p.S942* | Nonsense Mutation (SNP) | VAF 22/294 reads (7%) | called by muse, mutect2
- TEPSIN | c.746T>G p.L249W | Missense Mutation (SNP) | VAF 28/416 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- THSD7A | c.611C>T p.S204F | Missense Mutation (SNP) | VAF 38/301 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TLL1 | c.2757G>A p.W919* | Nonsense Mutation (SNP) | VAF 50/902 reads (6%) | called by muse, mutect2
- TMC6 | c.1339G>A p.G447S | Missense Mutation (SNP) | VAF 60/621 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.78); called by muse, mutect2
- TMC6 | c.1337T>A p.L446Q | Missense Mutation (SNP) | VAF 56/621 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.396); called by muse, mutect2
- TMEFF1 | c.1001C>G p.A334G | Missense Mutation (SNP) | VAF 20/458 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); called by muse, mutect2
- TMEM131L | c.3677C>T p.A1226V | Missense Mutation (SNP) | VAF 26/702 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2
- TPRKB | c.441+5G>C | Splice Region (SNP) | VAF 22/267 reads (8%) | called by muse, mutect2
- TRMT6 | c.79G>A p.V27M | Missense Mutation (SNP) | VAF 21/286 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- TSHZ2 | c.606C>A p.S202R | Missense Mutation (SNP) | VAF 30/277 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- TTN | c.58112C>A p.P19371H (on ENST00000591111; = p.P11947H on NM_003319.4) | Missense Mutation (SNP) | VAF 16/192 reads (8%) | PolyPhen probably damaging (0.961); called by muse, mutect2
- UNC5D | c.402C>G p.C134W | Missense Mutation (SNP) | VAF 32/558 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- UNC79 | c.5662G>T p.A1888S (on ENST00000393151 / NM_001346218.2; = p.A1711S on NM_020818.5) | Missense Mutation (SNP) | VAF 68/525 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- USH2A | c.10493T>A p.V3498E | Missense Mutation (SNP) | VAF 51/473 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- USP40 | c.1697G>A p.G566E | Missense Mutation (SNP) | VAF 34/260 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- USP41 | c.40G>T p.V14L | Missense Mutation (SNP) | VAF 32/414 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.205); called by muse, mutect2
- UTS2 | c.308T>G p.L103W | Missense Mutation (SNP) | VAF 51/522 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- WDR55 | c.52G>A p.D18N | Missense Mutation (SNP) | VAF 36/478 reads (8%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.035); called by muse, mutect2
- WDR81 | c.3063G>C p.E1021D | Missense Mutation (SNP) | VAF 46/326 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- XIRP2 | c.5825C>A p.A1942D (on ENST00000628543; = p.A2117D on NM_152381.6) | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.04); called by muse, varscan2
- YTHDF1 | c.232G>T p.A78S | Missense Mutation (SNP) | VAF 28/410 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.04); called by muse, mutect2
- ZBTB7A | c.1513G>A p.G505S | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.026); called by mutect2, varscan2
- ZFP62 | c.437G>A p.C146Y (on ENST00000502412 / NM_001377944.1; = p.C113Y on NM_152283.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/407 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF17 | c.351A>C p.Q117H | Missense Mutation (SNP) | VAF 16/218 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.506); called by muse, mutect2
- ZNF449 | c.834G>T p.E278D | Missense Mutation (SNP) | VAF 39/157 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- ZNF831 | c.62C>A p.P21H | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- ZNF831 | c.2699G>C p.R900T | Missense Mutation (SNP) | VAF 16/165 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0.025); called by muse, mutect2
- ACLY | c.1155G>A p.Q385= | Silent (SNP) | VAF 20/269 reads (7%) | catalogued as rs782445117; called by muse, mutect2
- ADAMTS2 | c.561G>A p.E187= | Silent (SNP) | VAF 64/858 reads (7%) | called by muse, mutect2
- ADAMTSL3 | c.1200C>T p.P400= | Silent (SNP) | VAF 12/151 reads (8%) | called by muse, mutect2
- AEBP1 | c.2754C>A p.I918= | Silent (SNP) | VAF 26/428 reads (6%) | called by muse, mutect2
- AFMID | c.354A>T p.G118= | Silent (SNP) | VAF 60/684 reads (9%) | called by muse, mutect2
- APOB | c.5457G>T p.L1819= | Silent (SNP) | VAF 48/612 reads (8%) | called by muse, mutect2
- APOE | c.625C>A p.R209= | Silent (SNP) | VAF 5/59 reads (8%) | called by muse, mutect2
- ARHGAP44 | c.162G>T p.L54= | Silent (SNP) | VAF 29/294 reads (10%) | catalogued as rs376421836; called by muse, mutect2, varscan2
- ATP4A | c.2043G>T p.L681= | Silent (SNP) | VAF 6/84 reads (7%) | called by muse, mutect2
- C6orf201 | c.343C>T p.L115= | Silent (SNP) | VAF 40/372 reads (11%) | called by muse, mutect2
- CACNA1I | c.1128C>A p.I376= | Silent (SNP) | VAF 28/316 reads (9%) | catalogued as rs1384453481; called by muse, mutect2
- CACNA2D1 | c.2328T>A p.T776= (on ENST00000356253 / NM_001366867.1; = p.T764= on NM_000722.4) | Silent (SNP) | VAF 84/492 reads (17%) | called by muse, mutect2, varscan2
- CCBE1 | c.42C>A p.G14= | Silent (SNP) | VAF 83/811 reads (10%) | called by muse, mutect2
- CCDC74A | c.1023G>T p.V341= | Silent (SNP) | VAF 32/281 reads (11%) | called by muse, mutect2, varscan2
- DACH2 | c.732T>C p.N244= | Silent (SNP) | VAF 43/250 reads (17%) | called by muse, mutect2, varscan2
- DCN | c.225G>T p.V75= | Silent (SNP) | VAF 44/496 reads (9%) | called by muse, mutect2
- DDX60L | c.135C>T p.S45= | Silent (SNP) | VAF 79/630 reads (13%) | called by muse, mutect2, varscan2
- DNAH17 | c.9678C>T p.F3226= | Silent (SNP) | VAF 22/460 reads (5%) | catalogued as rs763280857, COSV67759050, COSV67760500; called by muse, mutect2
- DNAH7 | c.11244A>C p.V3748= | Silent (SNP) | VAF 25/475 reads (5%) | called by muse, mutect2
- DOCK2 | c.1740C>A p.A580= | Silent (SNP) | VAF 22/300 reads (7%) | called by muse, mutect2
- EGFLAM | c.87C>T p.I29= | Silent (SNP) | VAF 19/448 reads (4%) | called by muse, mutect2
- EIF2AK3 | c.3261G>T p.V1087= | Silent (SNP) | VAF 67/820 reads (8%) | called by muse, mutect2
- EPHA3 | c.1953C>A p.A651= | Silent (SNP) | VAF 38/456 reads (8%) | catalogued as COSV60711757; called by muse, mutect2
- FCGR1A | c.288A>C p.I96= | Silent (SNP) | VAF 184/1554 reads (12%) | called by muse, mutect2
- FOXD4L5 | c.861C>A p.G287= | Silent (SNP) | VAF 200/2013 reads (10%) | catalogued as rs1341767511, COSV66241341; called by muse, mutect2, varscan2
- GABRB3 | c.123G>T p.V41= | Silent (SNP) | VAF 24/550 reads (4%) | called by muse, mutect2
- HAS1 | c.1602C>G p.R534= | Silent (SNP) | VAF 14/172 reads (8%) | catalogued as COSV55787127; called by muse, mutect2
- HHIP | c.1692T>A p.I564= | Silent (SNP) | VAF 14/320 reads (4%) | called by muse, mutect2
- HK2 | c.2553G>A p.L851= | Silent (SNP) | VAF 48/530 reads (9%) | catalogued as rs1368527601; called by muse, mutect2
- HOXB9 | c.384G>T p.L128= | Silent (SNP) | VAF 32/400 reads (8%) | called by muse, mutect2
- HSPA6 | c.978C>A p.A326= | Silent (SNP) | VAF 37/1024 reads (4%) | called by muse, mutect2
- HTR7 | c.1047C>A p.A349= | Silent (SNP) | VAF 13/272 reads (5%) | called by muse, mutect2
- IL1RL1 | c.492A>T p.S164= | Silent (SNP) | VAF 50/662 reads (8%) | called by muse, mutect2
- KCNH5 | c.2256G>T p.V752= | Silent (SNP) | VAF 53/436 reads (12%) | called by muse, mutect2, varscan2
- KCNT2 | c.393C>A p.I131= | Silent (SNP) | VAF 25/245 reads (10%) | called by muse, mutect2, varscan2
- KRTAP10-7 | c.1086C>A p.P362= | Silent (SNP) | VAF 8/58 reads (14%) | called by muse, mutect2
- KRTAP10-9 | c.555T>A p.P185= | Silent (SNP) | VAF 83/878 reads (9%) | called by muse, mutect2
- LAMP5 | c.624C>A p.I208= | Silent (SNP) | VAF 29/407 reads (7%) | called by muse, mutect2
- LILRB3 | c.261C>A p.S87= | Silent (SNP) | VAF 90/1638 reads (5%) | called by muse, mutect2
- LRP1B | c.5310C>T p.I1770= | Silent (SNP) | VAF 38/474 reads (8%) | catalogued as rs180963536; called by muse, mutect2
- MAGI1 | c.4266C>T p.D1422= | Silent (SNP) | VAF 46/440 reads (10%) | called by muse, mutect2
- MS4A12 | c.195G>T p.P65= | Silent (SNP) | VAF 44/317 reads (14%) | called by muse, mutect2, varscan2
- MTSS2 | c.582G>T p.R194= | Silent (SNP) | VAF 34/305 reads (11%) | called by muse, mutect2, varscan2
- MTTP | c.1032C>A p.I344= | Silent (SNP) | VAF 84/892 reads (9%) | catalogued as rs1170411942; called by muse, mutect2
- MUC16 | c.1137C>T p.T379= | Silent (SNP) | VAF 22/272 reads (8%) | catalogued as COSV67494443; called by muse, mutect2
- NCAPH | c.1230G>T p.G410= | Silent (SNP) | VAF 25/265 reads (9%) | called by muse, mutect2
- NDST4 | c.1014G>A p.Q338= | Silent (SNP) | VAF 15/360 reads (4%) | called by muse, mutect2
- OR10R2 | c.408T>A p.G136= | Silent (SNP) | VAF 119/777 reads (15%) | called by muse, mutect2, varscan2
- OR2L13 | c.852C>A p.L284= | Silent (SNP) | VAF 68/584 reads (12%) | called by muse, mutect2, varscan2
- OR2L3 | c.783A>G p.P261= | Silent (SNP) | VAF 34/512 reads (7%) | called by muse, mutect2
- PAK2 | c.1500G>T p.L500= | Silent (SNP) | VAF 70/265 reads (26%) | called by muse, mutect2, varscan2
- PCDH17 | c.3333C>A p.S1111= | Silent (SNP) | VAF 59/786 reads (8%) | catalogued as COSV64978092; called by muse, mutect2
- PDE1C | c.252G>T p.L84= | Silent (SNP) | VAF 28/268 reads (10%) | called by muse, mutect2
- PIP5K1C | c.969G>A p.V323= | Silent (SNP) | VAF 28/372 reads (8%) | called by muse, mutect2
- PSMC6 | c.33G>T p.R11= | Silent (SNP) | VAF 68/404 reads (17%) | called by muse, varscan2
- PTPRG | c.279G>T p.A93= | Silent (SNP) | VAF 52/499 reads (10%) | catalogued as COSV55639880; called by muse, mutect2, varscan2
- ROBO2 | c.2277C>T p.S759= | Silent (SNP) | VAF 43/840 reads (5%) | called by muse, mutect2
- RP1 | c.2193C>A p.L731= | Silent (SNP) | VAF 23/620 reads (4%) | called by muse, mutect2
- RUNDC1 | c.1191G>A p.L397= | Silent (SNP) | VAF 31/266 reads (12%) | called by muse, mutect2, varscan2
- SALL3 | c.3261C>T p.P1087= | Silent (SNP) | VAF 12/149 reads (8%) | catalogued as rs1285342877; called by muse, mutect2
- SGK2 | c.237C>T p.N79= | Silent (SNP) | VAF 36/481 reads (7%) | called by muse, mutect2
- SLC24A3 | c.1410G>T p.P470= | Silent (SNP) | VAF 39/677 reads (6%) | called by muse, mutect2
- SLC25A31 | c.48C>T p.D16= | Silent (SNP) | VAF 34/516 reads (7%) | catalogued as rs761883245, COSV55418278; called by muse, mutect2
- SLC52A3 | c.87G>C p.L29= | Silent (SNP) | VAF 18/154 reads (12%) | called by muse, mutect2, varscan2
- SLIT3 | c.4107G>T p.R1369= | Silent (SNP) | VAF 20/138 reads (14%) | catalogued as COSV60606809, COSV60616265; called by muse, varscan2
- SOCS6 | c.297C>G p.A99= | Silent (SNP) | VAF 40/395 reads (10%) | catalogued as COSV67547047; called by muse, mutect2, varscan2
- SORCS1 | c.3475C>A p.R1159= | Silent (SNP) | VAF 40/612 reads (7%) | catalogued as COSV53899675; called by muse, mutect2
- SPTA1 | c.2320C>A p.R774= | Silent (SNP) | VAF 107/1057 reads (10%) | catalogued as COSV100934740; called by muse, mutect2
- SVOP | c.513C>A p.P171= | Silent (SNP) | VAF 37/405 reads (9%) | catalogued as COSV54469765; called by muse, mutect2
- TDRD6 | c.1224G>A p.K408= | Silent (SNP) | VAF 20/390 reads (5%) | catalogued as rs1308873020; called by muse, mutect2
- TNNI3 | c.423G>T p.R141= | Silent (SNP) | VAF 51/513 reads (10%) | called by muse, mutect2, varscan2
- WDR7 | c.2544G>T p.L848= | Silent (SNP) | VAF 18/259 reads (7%) | called by muse, mutect2
- WDR87 | c.2751C>T p.A917= | Silent (SNP) | VAF 22/228 reads (10%) | called by muse, mutect2, varscan2
- WFIKKN2 | c.1680C>T p.V560= | Silent (SNP) | VAF 8/34 reads (24%) | called by muse, mutect2
- WNK2 | c.96G>A p.K32= | Silent (SNP) | VAF 24/90 reads (27%) | called by muse, mutect2, varscan2
- AC073621.1 | n.537C>A | RNA (SNP) | VAF 20/290 reads (7%) | called by muse, mutect2
- ADAM20P1 | n.789G>T | RNA (SNP) | VAF 43/306 reads (14%) | called by muse, mutect2, varscan2
- APOOP5 | n.238C>A | RNA (SNP) | VAF 38/418 reads (9%) | called by muse, mutect2
- BIRC7 | c.450-121G>T | Intron (SNP) | VAF 19/253 reads (8%) | called by muse, mutect2
- COA5 | c.100-25A>C | Intron (SNP) | VAF 20/512 reads (4%) | called by muse, mutect2
- ERLIN2 | c.424+109G>T | Intron (SNP) | VAF 17/413 reads (4%) | catalogued as COSV99379795; called by muse, mutect2
- ETNK1 | c.-5G>T | 5'UTR (SNP) | VAF 56/734 reads (8%) | called by muse, mutect2
- FGB | c.*39A>G | 3'UTR (SNP) | VAF 34/546 reads (6%) | called by muse, mutect2
- HTR1A | c.-12G>T | 5'UTR (SNP) | VAF 56/626 reads (9%) | called by muse, mutect2
- MGAT4A | c.*4105A>G | 3'UTR (SNP) | VAF 45/500 reads (9%) | called by muse, mutect2
- MIR323A | n.20G>T | RNA (SNP) | VAF 44/458 reads (10%) | called by muse, mutect2
- MRPL27 | c.-6G>A | 5'UTR (SNP) | VAF 52/604 reads (9%) | called by muse, mutect2
- MYT1L | c.*583C>A | 3'UTR (SNP) | VAF 38/354 reads (11%) | called by muse, mutect2, varscan2
- NOC2LP2 | n.1106G>T | RNA (SNP) | VAF 18/131 reads (14%) | catalogued as rs770149657; called by mutect2, varscan2
- OBSCN | c.11659+4895A>G | Intron (SNP) | VAF 75/686 reads (11%) | catalogued as rs748670637; called by muse, mutect2, varscan2
- OR10Z1 | chr1:158611435 T>G | 3'Flank (SNP) | VAF 30/182 reads (16%) | catalogued as COSV63525914; called by muse, mutect2, varscan2
- PHKG1 | c.-5T>C | 5'UTR (SNP) | VAF 18/274 reads (7%) | called by muse, mutect2
- PPIL2 | c.714+775A>T | Intron (SNP) | VAF 44/331 reads (13%) | called by muse, mutect2, varscan2
- PTPRO | c.-10C>T | 5'UTR (SNP) | VAF 64/663 reads (10%) | called by muse, mutect2, varscan2
- RFK | chr9:76398763 G>T | 5'Flank (SNP) | VAF 89/763 reads (12%) | called by muse, mutect2, varscan2
- RNMT | c.*3083C>T | 3'UTR (SNP) | VAF 29/245 reads (12%) | called by muse, mutect2, varscan2
- RPS4X | c.361-480A>G | Intron (SNP) | VAF 59/254 reads (23%) | called by muse, mutect2, varscan2
- SIRPB2 | c.-52C>A | 5'UTR (SNP) | VAF 16/208 reads (8%) | called by muse, mutect2
- SLC3A2 | c.299-4226G>T | Intron (SNP) | VAF 10/204 reads (5%) | called by muse, mutect2
- SNORD116-17 | chr15:25088002 C>T | 3'Flank (SNP) | VAF 24/421 reads (6%) | catalogued as rs772234705; called by muse, mutect2
- SSPOP | n.1217_1218delinsT | RNA (DEL) | VAF 40/325 reads (12%) | called by pindel, varscan2*
- STON1 | chr2:48530031 G>T | 5'Flank (SNP) | VAF 9/81 reads (11%) | catalogued as rs777313532; called by muse, mutect2, varscan2
- SYT9 | c.1044+289G>A | Intron (SNP) | VAF 20/202 reads (10%) | catalogued as rs772364855, COSV100608610; called by muse, mutect2
- TBX3 | c.657+56C>G | Intron (SNP) | VAF 72/627 reads (11%) | called by muse, mutect2, varscan2
- TEAD4 | c.2dup p.M1Ffs*? | 5'UTR (INS) | VAF 5/46 reads (11%) | called by mutect2, pindel, varscan2
- VSX2 | c.-51G>T | 5'UTR (SNP) | VAF 32/188 reads (17%) | catalogued as rs1021047045; called by muse, mutect2, varscan2
